Gene-level copy-number profile of tumor specimen TCGA-55-8510-01A from TCGA case TCGA-55-8510, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 55.9 years (20,410 days).
Specimen TCGA-55-8510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b9aad986-ad82-4366-b51e-8895eff15463.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8510-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b3d984a1-a382-4454-b163-0aeb47a48e9f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 23,377; copy number 2: 27,132; copy number 3: 8,053; copy number 4: 762; copy number 5: 244; copy number 6: 249.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8510-01A-11D-2389-01): tumor purity 0.28, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 493 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–29,983,114, 451 genes, copy number 5–6 (broad region; genes not listed).
- chr5:37,106,228–37,249,421, 1 gene, copy number 5 (within-gene range 4–5): CPLANE1.
- chr5:37,209,364–39,462,300, 41 genes, copy number 5: OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2.

Autosomal genes at a single copy (total copy number 1): 22,859. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
